TCGA case TCGA-YU-A94H — Testicular Germ Cell Tumors (TCGA-TGCT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Germ Cell Neoplasms; Primary site: Testis. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d80616c8-53f0-4c8b-a322-3d4999787b2a

Demographics
Sex at birth: male; Race: white; Country of residence at enrollment: Brazil; Age at index: 29 years; Year of birth: 1984; Vital status: Alive.

Diagnoses (1)
1. Seminoma, NOS: ICD-O-3 morphology code: 9061/3; ICD-10 code: C62.9; Tissue or organ of origin: Testis, NOS; Site of resection or biopsy: Testis, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 29.4 years (10,728 days); Year of diagnosis: 2013; Method of diagnosis: Orchiectomy; AJCC staging edition: 7th; AJCC clinical N: N0; AJCC clinical M: M0; AJCC clinical stage: Stage IA; AJCC pathologic T: T1; AJCC pathologic stage: Stage IA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 580 days (1.6 years); Ajcc serum tumor markers: S0; Sites of involvement: Rete Testis / Tunica Albuginea.
   Pathology details: Lymph node dissection site: Retroperitoneal; Lymph nodes removed: No; Timepoint category: Postoperative.
   Pathology details: Intratubular germ cell neoplasia present: Yes; Lymphatic invasion present: No; Vascular invasion present: No.
   Treatment given: Treatment type: Surgery, NOS; Treatment anatomic sites: Testis.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (4 entries)
- Days to follow up: 244 days; Disease response: Tumor Free.
- Days to follow up: 403 days (1.1 years); Disease response: Tumor Free.
- Days to follow up: 445 days (1.2 years); Disease response: Tumor Free.
- Follow-up contacts recording only the day: day 580, follow-up.

Molecular and laboratory tests (laboratory values one line per visit day)
- Day -13: Lactate Dehydrogenase 246; Alpha Fetoprotein 2.9; Human Chorionic Gonadotropin 1.1.
- Day 216: Lactate Dehydrogenase 327; Alpha Fetoprotein 3.5.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Fertility history: Did not attempt to reproduce; Undescended testis history: No.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-YU-A94H-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 190 mg.
  Slide TCGA-YU-A94H-01A-01-TSA: Section location: Top; Percent tumor cells: 65; Percent tumor nuclei: 65; Percent normal cells: 8; Percent necrosis: 0; Percent stromal cells: 27; Percent lymphocyte infiltration: 8; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 2.
- Sample TCGA-YU-A94H-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-YU-A94H-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
